Gene-level copy-number profile of tumor specimen TCGA-61-1722-01A from TCGA case TCGA-61-1722, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-61-1722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b37b89ba-4a07-4bc7-85ae-932db8485ef0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1722-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e8a94db-e327-465c-8b11-499b53d1c077

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,208; copy number 2: 34,831; copy number 3: 11,539; copy number 4: 7,374; copy number 5: 447; copy number 6: 3; copy number 7: 51; copy number 8: 107; copy number 9: 69; copy number 10: 59; copy number 11: 2; copy number 12: 2; copy number 14: 96; copy number 15: 10; copy number 16: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1722-01A-01D-0577-01): tumor purity 0.55, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 857 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,711,277–30,860,254, 9 genes, copy number 7: MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1.
- chr1:34,640,157–43,705,518, 283 genes, copy number 8–14 (within-gene range 4–14) (broad region; genes not listed).
- chr1:71,081,324–71,489,976, 2 genes, copy number 11 (within-gene range 2–11): ZRANB2-AS2, AL358453.1.
- chr3:168,008,689–170,860,993, 56 genes, copy number 5 (within-gene range 4–5): GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2.
- chr8:41,426,655–42,796,392, 40 genes, copy number 5: SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6.
- chr11:77,322,017–79,612,300, 46 genes, copy number 14: PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1.
- chr11:110,355,130–110,464,884, 2 genes, copy number 10 (within-gene range 5–10): LINC02732, FDX1.
- chr12:68,686,951–68,745,809, 1 gene, copy number 5 (within-gene range 3–5): NUP107.
- chr12:68,746,125–70,637,440, 43 genes, copy number 5–7 (within-gene range 3–7): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:70,906,917–74,402,600, 38 genes, copy number 5 (within-gene range 3–5): Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3.
- chr14:67,819,779–68,736,678, 13 genes, copy number 6–15 (within-gene range 3–15): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1.
- chr17:959,034–2,063,241, 46 genes, copy number 5: AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2, AC016292.1, AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1, RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1.
- chr17:2,072,823–2,122,508, 5 genes, copy number 5: AC090617.9, AC090617.4, AC090617.6, AC090617.8, AC090617.7.
- chr18:6,727,053–15,330,282, 241 genes, copy number 5–7 (broad region; genes not listed).
- chr18:72,536,680–74,598,885, 30 genes, copy number 5–16 (within-gene range 1–16): CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922, DIPK1C, AC009704.3, CNDP2, AC009704.2, CNDP1, AC009704.1, LINC00909.
- chr18:77,249,848–77,277,900, 1 gene, copy number 12: GALR1.
- chr18:77,431,563–77,431,689, 1 gene, copy number 12: AC124254.1.

Autosomal genes at a single copy (total copy number 1): 3,815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
